Somatic mutation profile of tumor specimen TCGA-AQ-A1H3-01A (aliquot TCGA-AQ-A1H3-01A-31D-A13L-09) from TCGA case TCGA-AQ-A1H3, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 49.8 years (18,177 days).
Specimen TCGA-AQ-A1H3-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 046bc460-a6d8-47f7-be3a-067ecb2c3ec9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AQ-A1H3-10A (Blood Derived Normal), aliquot TCGA-AQ-A1H3-10A-01D-A188-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/911c73d2-935f-4199-a0f8-4c00285b7bf9

The open-access MAF lists 26 somatic variants for this specimen: 17 protein-altering or splice-affecting, 9 silent.
By variant classification: Missense Mutation 11, Silent 9, Frame Shift Ins 3, Nonsense Mutation 1, Splice Site 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARHGEF6 | c.406C>G p.Q136E | Missense Mutation (SNP) | VAF 77/254 reads (30%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.006); catalogued as COSV51690332; called by muse, mutect2, varscan2
- CHD4 | c.2591G>A p.R864Q (on ENST00000357008 / NM_001363606.2; = p.R877Q on NM_001273.5) | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV58900818; called by muse, mutect2, varscan2
- CSNK1A1L | c.690dup p.Q231Tfs*4 | Frame Shift Ins (INS) | VAF 80/360 reads (22%) | catalogued as rs369743261; called by mutect2, varscan2
- EXTL3 | c.2361C>G p.Y787* | Nonsense Mutation (SNP) | VAF 57/156 reads (37%) | catalogued as COSV55037914; called by muse, mutect2, varscan2
- GATA2 | c.1114G>A p.A372T | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM141458, COSV62002954; called by mutect2, varscan2
- HEATR4 | c.1636C>T p.R546W | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs769490211, COSV58572475; called by muse, mutect2, varscan2
- INSRR | c.437A>T p.E146V | Missense Mutation (SNP) | VAF 20/28 reads (71%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.977); catalogued as COSV63872928; called by muse, mutect2, varscan2
- KIAA2013 | c.1739A>G p.D580G | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.396); catalogued as COSV64860612; called by muse, mutect2, varscan2
- LRP1B | c.12367A>G p.I4123V | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV67216549; called by muse, mutect2, varscan2
- PCDHA3 | c.103G>A p.V35I | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.123); catalogued as rs1554121379, COSV65366871; called by muse, mutect2, varscan2
- RB1CC1 | c.199-2A>C p.X67_splice | Splice Site (SNP) | VAF 8/30 reads (27%) | catalogued as COSV50248139; called by muse, mutect2, varscan2
- SIX6 | c.203G>A p.R68H | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.031); catalogued as COSV59802131; called by muse, mutect2, varscan2
- SNX17 | c.1034G>A p.R345H | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as rs1177962637, COSV52007734; called by muse, mutect2, varscan2
- SYT7 | c.505G>A p.G169S | Missense Mutation (SNP) | VAF 6/95 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99802109; called by muse, mutect2
- CBFB | c.267_270del p.R90Kfs*7 | Frame Shift Del (DEL) | VAF 25/63 reads (40%) | called by mutect2, pindel, varscan2
- CDKN1B | c.234_235dup p.V79Gfs*41 | Frame Shift Ins (INS) | VAF 8/37 reads (22%) | called by mutect2, pindel, varscan2
- TBX3 | c.887dup p.N296Kfs*31 (on ENST00000257566 / NM_016569.4; = p.N276Kfs*31 on NM_005996.4) | Frame Shift Ins (INS) | VAF 40/199 reads (20%) | called by mutect2, pindel, varscan2
- CD33 | c.690C>T p.N230= | Silent (SNP) | VAF 23/56 reads (41%) | catalogued as rs781358706, COSV51801688; called by muse, mutect2, varscan2
- COL7A1 | c.498G>A p.Q166= | Silent (SNP) | VAF 12/40 reads (30%) | catalogued as rs953698548, COSV60394955; called by muse, mutect2, varscan2
- DUOX2 | c.3939C>T p.T1313= | Silent (SNP) | VAF 24/51 reads (47%) | catalogued as rs767720307, COSV66532020, COSV66534103; called by muse, mutect2, varscan2
- FGFR1 | c.51A>G p.T17= | Silent (SNP) | VAF 15/68 reads (22%) | catalogued as rs886286139, COSV58334010; called by muse, mutect2, varscan2
- MECOM | c.3117G>A p.A1039= (on ENST00000468789 / NM_001105078.4; = p.A1227= on NM_004991.4) | Silent (SNP) | VAF 29/86 reads (34%) | catalogued as rs750896996, COSV52964010; called by muse, mutect2, varscan2
- NFIA | c.1035G>A p.A345= | Silent (SNP) | VAF 20/77 reads (26%) | catalogued as rs1051141398, COSV64537202; called by muse, mutect2, varscan2
- PAPOLB | c.618G>A p.R206= | Silent (SNP) | VAF 103/249 reads (41%) | catalogued as COSV68200689; called by muse, mutect2, varscan2
- PCDHGA3 | c.2328G>A p.A776= | Silent (SNP) | VAF 32/141 reads (23%) | catalogued as rs755956350, COSV53943731; called by muse, mutect2, varscan2
- RYR3 | c.6714C>T p.N2238= | Silent (SNP) | VAF 9/39 reads (23%) | catalogued as rs377229802; ClinVar: likely benign; called by muse, mutect2, varscan2
